Surgical pathology report (de-identified scan), TCGA case TCGA-56-5898, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-5898-01A (Primary Tumor).

[page 1 of 3]
Collection Date: [REDACTED]
Hospital of Origin:
Copy to

QC Pathologist:

FINAL PATHOLOGIC DIAGNOSIS:

A. Lung, right upper lobe, wedge resection:
Squamous cell carcinoma, keratinizing type.

Size: 3.0 x 1.5 cm.

Grade: II.

No pleural invasion.

No lymphovascular space invasion.

Surgical margins free of tumor.

Tumor distance to pleural surface: 2 mm.

B. Lymph node, level 10, biopsy:

Negative for neoplasm, one node examined (0/1).

C. Lung, right upper lobe, lobectomy:

Emphysematous change and hemorrhage from previous excision.

No residual neoplasm.

D. Lymph node, level 7, biopsy:

Negative for neoplasm, one node examined (0/1).

Staging [REDACTED] pT1, N0, M0

COMMENTS:

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Right upper lobe mass with frozen section

B. Right lung level 10 lymph node

C. Right lung upper lobe

D. Right lung level 7 lymph node

CODES:

PROCEDURAL DEMOGRAPHICS:

Date of Procedure: [REDACTED]

Accession Date/Time: [REDACTED]

[page 2 of 3]
GROSS DESCRIPTION:

The specimen is received in four containers labeled

A. Additionally labeled right upper lobe mass and contains an 8.5 x 5.4 x 2.0 cm lung wedge. The pleura is purple gray and glistening. The staple line is removed and the underlying parenchyma is inked black. The specimen is serially sectioned to reveal a 3.0 x 1.5 x 1.0 cm ill defined gray white mass that approaches to within 0.1 cm of the inked parenchymal margin and to within 0.2 cm of the pleural surface. The remainder of the cut surface is beefy red, spongy with focally dilated air spaces. Representative sections are submitted for frozen section with the residual entirely resubmitted for permanent section in cassette A1 labeled [redacted] Additional representative sections are submitted in cassettes A1-A7 designated as follows: A2-- inked parenchymal margin, perpendicular; A3-A7-- remainder of mass. Additionally, a yellow and green cassette are submitted for genomic research each labeled [redacted]

B. Additionally labeled right lung level 10 lymph node and contains a 1.4 cm gray black rubbery, friable soft tissue consistent with lymph node. The specimen is bisected and entirely submitted in cassette B labeled [redacted]

C. Additionally labeled right upper lobe and contains a 13.5 x 8.5 x 5.0 cm lung lobe surfaced by purple gray glistening pleura. A 0.5 cm in length by 1.4 cm diameter segment of exposed bronchus is present. Adjacent to the bronchus are segments of stapled vasculature as well as two serpiginous staple lines. The first is 9.5 and the second is 12.0 cm in length. The staple lines are removed and the underlying parenchyma is inked black. The specimen is serially sectioned to reveal a red pink, hemorrhagic, congested cut surface. No masses or areas of consolidation are identified. Representative sections are submitted in cassettes C1-C5 labeled [redacted] designated as follows: 1-- bronchial and vascular margins, en face; 2-- first staple line, perpendicular; 3-- second staple line, perpendicular; 4-5-- representative parenchyma.

D. Additionally labeled right lung level 7 lymph node and contains a 2.0 cm gray black friable, soft tissue consistent with lymph node. The specimen is bisected and entirely submitted in cassette D labeled [redacted]

INTRA-PROCEDURE CONSULTATION:

A. Frozen section diagnosis: Lung, right upper lobe
Squamous cell carcinoma per Dr. [redacted]

[page 3 of 3]
FULL RESULT:

Indication: Low oxygen saturation. Right lower lobe atelectasis.

Comparison: [REDACTED]

Procedure: Portable chest.

Findings: Right sided chest tube remains in place with its tip at the right lung apex. There is no pleural fluid.

Near-complete opacification of the right hemithorax on the prior examination is improved although there is persistent opacity especially at the right base. There is mild linear and interstitial opacity at the left base which has increased. The left upper lung is clear.

IMPRESSION:

Interval improved aeration of the right lung with increased mild left basilar opacity.

Source: NCI Genomic Data Commons file 36e378cf-2bc4-43ba-97bb-e49b27c96426 (TCGA-56-5898.04CA3E3E-CA70-4616-B7BA-8D48D88007BD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).